Gene-level copy-number profile of tumor specimen TCGA-NQ-A638-01A from TCGA case TCGA-NQ-A638, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 66.8 years (24,410 days).
Specimen TCGA-NQ-A638-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-MESO.11ff78ca-f433-4d8c-b8ea-45b46289f415.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NQ-A638-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/90133593-10c8-4367-bd6a-270d77bad27a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 140; copy number 1: 3,495; copy number 2: 14,125; copy number 3: 31,201; copy number 4: 10,857.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NQ-A638-01A-11D-A34B-01): tumor purity 0.61, ploidy 2.84, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 140 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,331,446–27,230,174, 103 genes (within-gene range 0–1) (broad region; genes not listed).
- chr9:27,829,276–32,334,354, 30 genes: AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.2, AL162388.1, AL353684.1, AL354676.1, ME2P1, LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4, HSPA8P17, AL354854.1, SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30, HMGB3P23, RNA5SP281, SLC25A5P8.
- chr9:32,629,454–32,820,350, 7 genes: TAF1L, AL589642.1, AL589642.2, SNRPCP1, AL157884.1, TMEM215, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,108. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
